Gene-level copy-number profile of tumor specimen TCGA-YU-A948-01A from TCGA case TCGA-YU-A948, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 17.9 years (6,548 days).
Specimen TCGA-YU-A948-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 080e68f2-32d6-43c6-8e6f-cae558026135.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-YU-A948-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/301ebcd9-01d2-4033-a3eb-7deac64f7083

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 592; copy number 2: 22,666; copy number 3: 31,479; copy number 4: 3,324; copy number 5: 136; copy number 6: 631; copy number 7: 31; copy number 8: 54.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 85 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:31,382,226–31,591,136, 1 gene, copy number 8 (within-gene range 6–8): DENND5B.
- chr12:31,443,792–34,249,958, 71 genes, copy number 7–8 (broad region; genes not listed).
- chr14:106,850,885–106,879,812, 6 genes, copy number 7: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr21:10,640,028–13,120,807, 7 genes, copy number 7: AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Autosomal genes at a single copy (total copy number 1): 70. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
